Somatic mutation profile of tumor specimen TCGA-AB-2803-03B (aliquot TCGA-AB-2803-03B-01W-0728-08) from TCGA case TCGA-AB-2803, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute promyelocytic leukaemia, t(15;17)(q22;q11-12); Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.8 years (22,584 days).
Specimen TCGA-AB-2803-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 323780cf-73f3-4183-9e29-5fdfd41a8409.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2803-11B (Solid Tissue Normal), aliquot TCGA-AB-2803-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe72064c-22b6-4118-a4cc-430562ad2fb2

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CC2D2A | c.3341C>T p.T1114M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386833752, CM094697, COSV67503825; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TUBA1A | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.093); catalogued as rs1064796460, CM130501, COSV55498955; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1S | c.1087C>T p.L363F | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs774552212, COSV62944049; called by muse, mutect2, varscan2
- FNIP2 | c.635G>A p.C212Y | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.111); catalogued as COSV52446353; called by muse, mutect2, varscan2
- FSD2 | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as rs376156057; called by muse, mutect2, varscan2
- LMOD1 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs772555355, COSV66172967; called by muse, mutect2, varscan2
- LNX1 | c.526G>A p.E176K (on ENST00000263925 / NM_001126328.3; = p.E80K on NM_032622.2) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs757156927, COSV55792145; called by muse, mutect2, varscan2
- PEX13 | c.478del p.A160Lfs*5 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | catalogued as COSV54370971; called by mutect2, pindel, varscan2
- POU5F1 | c.717C>A p.N239K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.346); catalogued as COSV52565096; called by muse, mutect2, varscan2
- RPL32 | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 74/167 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV55994993; called by muse, mutect2, varscan2
- RYR3 | c.8521G>A p.V2841I (on ENST00000389232; = p.V2842I on NM_001036.6) | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs1422881357, COSV66809438; called by muse, mutect2, varscan2
- TRIM48 | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV70162023, COSV70163372; called by muse, mutect2, varscan2
- KRTAP9-9 | c.267C>T p.S89= | Silent (SNP) | VAF 102/217 reads (47%) | catalogued as COSV61898779; called by muse, mutect2, varscan2
- TAS2R38 | c.936G>C p.L312= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV71886126; called by muse, mutect2, varscan2
- ZBED6CL | c.553C>T p.L185= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV59605430; called by muse, mutect2, varscan2
